Surgical pathology report (de-identified scan), TCGA case TCGA-BC-A216, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UNC, specimen TCGA-BC-A216-01A (Primary Tumor).

[page 1 of 4]
ICB-0-3
carcinoma, hepatocellular, NOS 8/76/3
Site: liver c22.0 ps 4/8/11

SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Liver, right lobe, extended right hepatic lobectomy
- Hepatocellular carcinoma, moderately differentiated, with
subset coagulative
necrosis (20%)
- Multifocal, largest nodule 7.5 cm diameter
- Invasive carcinoma involves capsule and margin at focus of
superior gross
capsular disruption (block A9)
- Vascular invasion - not identified
- Surgical margins - Focally positive at superior gross capsular
disruption
(block A9), other margins negative (see Light Microscopy)
- Non-neoplastic parenchyma - mild portal chronic inflammation,
without
significant fibrosis
- AJCC staging: pT3 pNx pMx

B: Liver, segment 2 margin, excision
- Hepatic parenchyma, no carcinoma identified

C: Liver, segment 3 margin, excision
- Hepatic parenchyma, no carcinoma identified

D: Diaphragm, NOS, excision
- Fibrous tissue and skeletal muscle with granulation tissue and
chronic
inflammation
- No carcinoma identified

E: Gallbladder, cholecystectomy
- No specific histologic abnormality
- No carcinoma identified

Clinical History:

10-year-old female with HCC in the right liver. Liver tumor.
Interval increase
in size of the solitary large right hepatic lobe mass concerning
for
hepatocellular carcinoma with involvement of the right portal
vein.

[page 2 of 4]
Gross Description:

Received are five appropriately labeled containers.

Container A is additionally labeled "extended right lobectomy" and is a 3,190 gram, 29 x 22 x 10 cm lobe of liver, red/tan, focally erythematous and adhered capsular surface. The capsule is intact with the exception of three foci of disruption (2 superior, 1 inferior) that have been inked yellow. The parenchymal margin is inked blue in addition to an adjacent portion of this specimen, containing an embedded staple line that is remarkable for tumor encapsulated within thin membranous tissue (true margin ?). Serial sectioning demonstrates a 21 x 16.5 x 10.5 cm well-circumscribed necrotic white/yellow mass with diffuse hemorrhage and a central 7.5 x 7 x 5.5 cm stellate, firm fibrous component. The mass grossly abuts, but is confined by the capsular surface and at closest approach, is 0.3 cm from the parenchymal margin. The uninvolved parenchyma is yellow/tan with a nutmeg appearance and is remarkable for a 3 x 2 x 1.5 cm focus of clustered white/pink, well-circumscribed satellite lesions. The cluster is located 4.0 cm from the larger mass, 1.0 cm from the parenchymal margin, and 0.2 cm from the overlying capsule.

Block Summary:

- A1 - Mass with respect to parenchymal margin
- A2 - Mass with respect to capsule
- A3 - Representative from questionable margin
- A4 - Representative fibrous area of mass
- A5 - Mass with respect to normal uninvolved
- A6-A7 - Representative central sections of mass
- A8 - Representative cluster of lesions
- A9 - Representative capsular disruption (one of the two superior disruptions)
- A10 - Representative normal uninvolved.

[page 3 of 4]
A portion of tumor and normal tissue were sent for tissue procurement.

Container B is additionally labeled "segment 2 margin, stitch marks margin", and is a 3.5 x 1.5 x 0.7 cm fragment of tan/red soft tissue containing a suture on one of its surfaces indicated as the final margin per the requisition (inked blue). The opposing cut surface is inked black and the specimen is serially sectioned to reveal a grossly unremarkable tan/pink cut surface with no discrete masses or lesions. The specimen is submitted entirely in blocks B1 and B2.

Container C is additionally labeled "segment 3 margin, stitch marks final margin", and consists of two fragments of pink/tan soft tissue containing a suture on one of their surfaces indicated as the final margin per the requisition. The first fragment is 6.2 x 2.7 x 0.3 cm in dimension. The final margin is inked blue and the opposing cut surface is inked black. The second fragment is 5.9 x 2.6 x 0.4 cm in dimension, The final margin is inked blue and the opposing cut surface is inked green. Both fragments are serially sectioned to reveal a grossly unremarkable tan/red cut surface with no identifiable masses or lesions. The first fragment is submitted entirely in block C1-C3 and the second fragment is submitted entirely in block C4-C7.

Container D is additionally labeled "diaphragm" and is a 2 x 2 x 0.6 cm aggregate of two fragments of red/pink soft tissue. The fragments are sectioned to reveal a grossly unremarkable cut surface and are submitted entirely in blocks D1 and D2, respectively.

Specimen E:

Previously opened: No

[page 4 of 4]
Measurements: 8.5 x 3.3 x 1.3 cm
External surface: Pink/tan, smooth and glistening with focal erythema and gray/green discoloration within the body
Wall thickness: 0.2 cm
Mucosa: Pink/tan and velvety with diffuse yellow/gold stippling
Stones present: No
Other comments: The lumen is filled with a viscous red/orange fluid.
Block #: E1

Light Microscopy:

Light microscopic examination is performed by Dr.

Hepatocellular carcinoma is present, with trabecular architecture, plate expansion, nuclear pleomorphism, and variable nucleolar prominence. Rare mitotic figures and apoptotic nuclei are present. Background liver does not appear cirrhotic. We do not know whether the superior capsular disruption sampled in block A9 is superseded by the separately submitted diaphragm in D.

Signature

Resident Physician:

Attending Pathologist:, MD PHD

I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Electronically Signed by:, MD PhD

Date

Source: NCI Genomic Data Commons file 3300faf5-fd85-4bc6-8ad7-2b2ade493ca4 (TCGA-BC-A216.28CDABB8-3172-4676-8F4A-8B91F2B8D85F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).